Gene-level copy-number profile of tumor specimen ALCH-B2VP-TTP1-A from ALCHEMIST case ALCH-B2VP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 82.7 years (30,189 days).
Specimen ALCH-B2VP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9e8d8a21-8c00-4f1b-8896-9acd5d995ff3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2VP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/6172a977-9e8f-4a42-bb57-fee600c9280d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 1,749; copy number 2: 56,126; copy number 3: 476; copy number 4: 7; copy number 5: 11.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,035,178–16,057,308, 2 genes: AL355994.2, CLCNKB.
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr2:54,545,368–54,546,677, 1 gene (within-gene range 0–3): AC092839.1.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr7:45,816,216–45,821,064, 3 genes: CICP20, AC096582.1, AC096582.2.
- chr7:56,805,336–56,882,146, 3 genes: CICP28, AC118758.2, AC118758.1.
- chr7:76,959,835–77,043,775, 8 genes (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr8:22,089,150–22,133,384, 3 genes: FAM160B2, NUDT18, HR.
- chr8:47,068,021–47,068,323, 1 gene: RN7SKP32.
- chr11:4,287,499–4,288,083, 1 gene: SSU72P4.
- chr12:53,816,185–53,816,479, 1 gene: RN7SKP289.
- chr21:45,478,266–45,478,326, 1 gene (within-gene range 0–2): MIR6815.
- chr22:49,960,768–49,964,072, 2 genes: PIM3, MIR6821.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,482,738–13,016,692, 7 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.

Autosomal genes at a single copy (total copy number 1): 1,314. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
